Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA7Q, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA7Q-01A (Primary Tumor).

ICD O-3

Carcinoma, transitional cell
8120/3

Site Bladder wall NOS
C67.9

12/3/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

"Bladder":

- Invasive urothelial carcinoma of high grade, vegetating, ulcerated infiltrative, of brownish color, measuring 4.6 x 3.3 x 2.7cm, affecting left and right upper posterior lateral wall, infiltrating muscularis propria and perivesical adipose tissue;
- Presence of perineural invasion;
- Angiolymphatic invasion not observed;
- Surgical margins free of neoplasia.

"Prostate":

- Prostate adenocarcinoma, usual acinar type, Gleason score 7 (3 +4) in the form of Microscopic focus (2.0 mm) in the right apex, without extension to extraprostatic tissues;
- Angiolymphatic and perineural invasions not observed
- Surgical margins of neoplasia;
- Nodular prostatic hyperplasia associated;
- Adjacent parenchyma without evidence of prostatic involvement by urothelial carcinoma.
- Seminal vesicles and deferent ducts free of neoplasia.

PATHOLOGIC STAGING

Topography	Morphology	Stage
Bladder, NOS	Transitional cell carcinoma, NOS	pT3a

Source: NCI Genomic Data Commons file e1a02ec5-9891-468e-a7ad-b92c9298063f (TCGA-4Z-AA7Q.5715E28F-8C16-48DD-B92B-568EFCD0CA8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).